Surgical pathology report (de-identified scan), TCGA case TCGA-SR-A6MZ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Tufts Medical Center, specimen TCGA-SR-A6MZ-01A (Primary Tumor).

[page 1 of 2]
Specimen:
Procedure:
Accessioned:
Reported:
Submitting Phys:

Patient:
Medical Record #:
DOB/Age/Sex: (Age: F
Location/Client:

Surgical Pathology Report

Final Diagnosis

ADRENAL TUMOR, ADRENALECTOMY:

- MULTIPLE PHEOCHROMOCYTOMAS. THE SPECIMEN CONTAINS AT LEAST FOUR CONTIGUOUS, BUT APPARENTLY SEPARATE, NODULES OF PHEOCHROMOCYTOMA, 0.8 - 2.5 CM IN GREATEST DIMENSION. THREE OF THE NODULES ARE ENTIRELY INTRA-ADRENAL, WHILE THE FOURTH BULGES THROUGH THE ADRENAL CAPSULE AND IS PARTLY EXTRA-ADRENAL. THE NODULES VARY IN CYTOLOGICAL APPEARANCE, CONSISTENT WITH SEPARATE NEOPLASMS RATHER THAN A SINGLE COARSELY NODULAR ONE. HYALINE GLOBULES ARE FOCALLY PROMINENT. THERE IS NO DEFINITE ADRENAL MEDULLARY HYPERPLASIA. THERE IS NO PERIADRENAL SOFT TISSUE INVASION, VASCULAR INVASION OR NECROSIS. MITOSES ARE NOT IDENTIFIED. ALL OF THE NODULES SHOW LOW OVERALL IMMUNOHISTOCHEMICAL STAINING FOR Ki67, WITH OCCASIONAL HOT SPOTS. OTHER IMMUNOHISTOCHEMICAL MARKERS ARE AS FOLLOWS:

CALCITONIN: NEGATIVE IN ALL NODULES (SLIDES A1-A4) (FOCAL NONSPECIFIC PIGMENT PRESENT IN CONTROLS AND CT-STAINED SLIDES).

S100: VARIABLE NUMBERS OF SUSTENTACULAR CELLS STAINED IN A PATCHY DISTRIBUTION.

NEUROFILAMENT: RARE TUMOR CELLS AND NEURONS POSITIVE. NO EVIDENCE OF COMPOSITE TUMOR.

SDHB: TUMOR CELLS POSITIVE, CONSISTENT WITH NORMAL SUCCINATE DEHYDROGENASE GENES.

COMMENT: The presence of multiple pheochromocytomas suggests the possibility of a hereditary tumor syndrome, most likely MEN2. Clinicopathologic correlation is recommended.

***Report Electronically Signed By

This certifies that the pathologist named above has personally conducted a microscopic examination (or gross examination only, where stated) of the described specimen(s) and has rendered or confirmed the final diagnosis(es).

Clinical History

{Not Provided}

Pre-Operative Diagnosis

{Not Provided}

Post-Operative Diagnosis

{Not Provided}

[page 2 of 2]
Gross Description

- A. PHEOCHROMOCYTOMA (FRESH) The specimen, labeled with the patient's name and medical record number, weighs 27 grams, is an intact 6.0 x 4.0 x 1.4 cm adrenal gland with a small amount of adherent fat. In the central portion of the gland is a bulging 2 cm nodule with a smooth, intact, grey capsule. A second, smooth nodular bulge (1 cm in greatest dimension) protrudes through the cortex adjacent to the larger distended area. Perpendicular sections through the area between the two bulges reveals two apparently separate, sharply circumscribed purple nodules with grey mottling, 2.5 x 2 x 2 cm (designated #1) and 1 x 0.8 x 0.8 cm (designated #4) in greatest dimension. Transverse sections of the entire gland reveal two additional apparently separate but contiguous, predominantly grey nodules measuring 2 x 1 x 0.9 cm (designated as #3) and 0.8 x 0.8 x 0.5 cm (designated #2) in greatest dimension. The remaining adrenal medulla is barely visible and shows no evidence of diffuse hyperplasia. The adrenal cortex is up to 1 mm thick and grossly unremarkable. Representative sections are submitted.

SECTION CODE

- A1: PERPENDICULAR SECTIONS THROUGH NODULES 1 AND 4 THROUGH INTERVENING CORTEX (NODULE 1 IS THE LARGER PIECE AND HAS A ROUND SHAPE).
A2: ADDITIONAL SECTION OF NODULE #1.
A3: NODULE #2 AND #3 (LARGER PIECE IS #3).
A4: ? NODULE #1 AND NODULE #4.
A5: NORMAL APPEARING ADRENAL GLAND.

Department of Pathology
- End of Report -

Page 2 of 2

Printed:

Source: NCI Genomic Data Commons file a6a52660-1de5-4328-b38b-c6d313961c7a (TCGA-SR-A6MZ.30C765ED-AECE-4AE3-BA4B-913AE0E8863B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).